Somatic mutation profile of tumor specimen TCGA-S9-A6TV-01A (aliquot TCGA-S9-A6TV-01A-12D-A34J-08) from TCGA case TCGA-S9-A6TV, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 50.2 years (18,321 days).
Specimen TCGA-S9-A6TV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 610c4a77-2ffe-46fa-8246-2a452c7c1952.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6TV-10B (Blood Derived Normal), aliquot TCGA-S9-A6TV-10B-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91398ded-d4ce-47ea-b640-e1595c1bbc8a

The open-access MAF lists 29 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 24, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 38/105 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AADAT | c.766A>T p.I256F | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100528676; called by muse, mutect2, varscan2
- ABHD2 | c.1069A>G p.K357E | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.371); catalogued as COSV100756390; called by muse, mutect2, varscan2
- AFF2 | c.2551G>T p.G851C | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99665166; called by muse, mutect2, varscan2
- ATP13A1 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.343); catalogued as rs778252756, COSV99366385; called by muse, mutect2, varscan2
- ATRX | c.6254G>C p.R2085P | Missense Mutation (SNP) | VAF 93/110 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM062435, COSV100971171; called by muse, mutect2, varscan2
- CDC42BPB | c.1417G>A p.G473S | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100775440, COSV100775527; called by muse, mutect2, varscan2
- CNNM3 | c.1462T>C p.Y488H | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0.285); catalogued as COSV100562742; called by muse, mutect2, varscan2
- CNOT1 | c.2956C>A p.H986N | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.045); catalogued as COSV99800725; called by muse, mutect2, varscan2
- DYNC2H1 | c.12010C>T p.R4004C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs768839818, COSV100519116; called by muse, mutect2, varscan2
- HS3ST1 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.701); catalogued as rs200959205; called by muse, mutect2, varscan2
- IFT74 | c.1771G>A p.V591M | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs762276916, COSV101197204; called by muse, mutect2
- MED16 | c.1488G>T p.Q496H | Missense Mutation (SNP) | VAF 51/62 reads (82%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.873); catalogued as COSV99516000; called by muse, mutect2, varscan2
- NDFIP2 | c.811T>C p.S271P | Missense Mutation (SNP) | VAF 69/123 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99519384; called by muse, mutect2, varscan2
- PCSK5 | c.3640T>C p.S1214P | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.132); catalogued as COSV101377595; called by muse, mutect2, varscan2
- PDE4D | c.1751A>G p.D584G (on ENST00000340635 / NM_001104631.2; = p.D448G on NM_006203.4) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100401992; called by muse, mutect2, varscan2
- PLXNB1 | c.6332C>T p.T2111M | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.81); catalogued as rs772213782, COSV99603124; called by mutect2, varscan2
- RYR2 | c.5239G>A p.G1747S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.532); catalogued as rs1553522190, COSV100771968, COSV63696153; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC12A1 | c.1669G>A p.A557T | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs756435918, COSV101119013; called by muse, mutect2, varscan2
- SLC4A2 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.049); catalogued as rs201141316; called by muse, mutect2, varscan2
- STK31 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV100669698, COSV100670189; called by muse, mutect2
- UBR5 | c.8145G>A p.W2715* | Nonsense Mutation (SNP) | VAF 10/149 reads (7%) | catalogued as COSV99641597; called by muse, mutect2
- USP6NL | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.53); catalogued as COSV99509903; called by muse, mutect2, varscan2
- WNT16 | c.935G>A p.R312H (on ENST00000222462 / NM_057168.2; = p.R302H on NM_016087.2) | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as rs554766007, COSV55975081; called by muse, mutect2, varscan2
- LHX1 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARID3C | c.750G>A p.L250= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as rs774346846, COSV99426974; called by mutect2, varscan2
- RASSF2 | c.384G>A p.R128= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs370756464; called by muse, mutect2, varscan2
- SPRR2D | c.90G>A p.P30= | Silent (SNP) | VAF 88/184 reads (48%) | catalogued as rs756954313, COSV64209055; called by muse, mutect2, varscan2
- TENM3 | c.5433G>A p.L1811= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV101305281; called by muse, mutect2, varscan2
